CCDI case PBBKAW — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/2cf20b1f-f3d5-4aa3-8347-76d5bce715ca

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 3.1 years (1,117 days).

Biospecimens (3 samples)
- Sample 0DAL9M: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DAL9N: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DAL9O: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
